Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A65Z, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A65Z-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: temporal lobe

Diagnosis: oligodendroglioma (grade 2 WHO)

Name of Pathologist:

ICD-O-3
Oligodendroglioma NOS
9450/3
Site ^{path} Brain, temporal lobe
C71.2
GCF Brain, supratentorial
C71.0
JW 4/19/13

Reviewer Initials: AW	Date (rev. wed): 3/29/13	

Source: NCI Genomic Data Commons file 98a9a0d5-80ec-4496-bc17-dce36c426826 (TCGA-QH-A65Z.BA60EA12-509F-4699-AADC-BA0CA105BDAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).